Somatic mutation profile of tumor specimen HCM-BROD-0231-C25-86M (aliquot HCM-BROD-0231-C25-86M-01D-A937-36) from HCMI case HCM-BROD-0231-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 68.9 years (25,156 days).
Specimen HCM-BROD-0231-C25-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 966043f1-3c26-45df-b805-61e436f9979e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0231-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0231-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2948bde1-aa66-4d4b-9483-74fe534c36b1

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, In Frame Del 2, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 145/146 reads (99%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ARID1A | c.3391C>G p.Q1131E | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV61376561, COSV61380004; called by mutect2, varscan2
- CARD11 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 234/453 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1298741148, COSV67802261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRXCR1 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 34/504 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.637); catalogued as rs577521620, COSV67670049; called by muse, mutect2
- MAN2A1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 99/214 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.152); catalogued as rs1359989748; called by muse, mutect2, varscan2
- NRXN1 | c.1769C>A p.S590Y | Missense Mutation (SNP) | VAF 161/389 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100453687; called by muse, mutect2, varscan2
- NT5DC2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs1268012937; called by muse, mutect2, varscan2
- POTEJ | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 117/395 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs764378487; called by muse, mutect2, varscan2
- SEC61A1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 209/454 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs767658338, COSV54578190; called by muse, mutect2, varscan2
- SHMT2 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 276/567 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs760592358, COSV61073422; called by muse, mutect2, varscan2
- SLC6A9 | c.1653C>T p.Y551= (on ENST00000360584 / NM_201649.4; = p.Y497= on NM_006934.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 158/325 reads (49%) | catalogued as rs200915117, COSV62212040; called by muse, mutect2, varscan2
- SLFN14 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 163/321 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1274661246; called by muse, mutect2, varscan2
- TBC1D10B | c.1489C>T p.L497F | Missense Mutation (SNP) | VAF 256/485 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374035939, COSV59768069; called by muse, mutect2, varscan2
- USH2A | c.9526C>A p.P3176T | Missense Mutation (SNP) | VAF 159/338 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.261); catalogued as COSV56356532; called by muse, mutect2, varscan2
- AANAT | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 145/444 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID1A | c.3398_3401del p.P1133Lfs*27 | Frame Shift Del (DEL) | VAF 193/208 reads (93%) | called by pindel, varscan2
- ATP1A4 | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 156/347 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRAF | c.1577_1591del p.N526_P530del (on ENST00000288602 / NM_001374244.1; = p.N486_P490del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 94/268 reads (35%) | called by mutect2, pindel, varscan2
- C11orf80 | c.1838A>G p.Q613R | Missense Mutation (SNP) | VAF 236/538 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); called by muse, mutect2
- C12orf42 | c.839T>C p.M280T | Missense Mutation (SNP) | VAF 317/682 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CTSB | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 17/568 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- DHX40 | c.1490G>A p.C497Y | Missense Mutation (SNP) | VAF 171/369 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- EPS8L2 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 228/425 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLGA1 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LRRFIP2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MTR | c.2519T>A p.M840K | Missense Mutation (SNP) | VAF 165/335 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PMPCA | c.783G>C p.E261D | Missense Mutation (SNP) | VAF 301/612 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPP1R36 | c.424_426del p.T142del | In Frame Del (DEL) | VAF 117/123 reads (95%) | called by pindel, varscan2
- SLCO3A1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 179/359 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRIM31 | c.12dup p.Q5Afs*81 | Frame Shift Ins (INS) | VAF 174/245 reads (71%) | called by mutect2, pindel, varscan2
- USF3 | c.1387A>G p.T463A | Missense Mutation (SNP) | VAF 218/475 reads (46%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZFHX4 | c.4022T>G p.V1341G | Missense Mutation (SNP) | VAF 204/428 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- BCAR1 | c.1584T>C p.N528= | Silent (SNP) | VAF 241/501 reads (48%) | called by muse, mutect2, varscan2
- CR2 | c.2172G>T p.V724= | Silent (SNP) | VAF 168/360 reads (47%) | called by muse, mutect2, varscan2
- MACF1 | c.13368C>G p.R4456= (on ENST00000372915; = p.R2389= on NM_012090.5) | Silent (SNP) | VAF 367/367 reads (100%) | called by muse, mutect2, varscan2
- PDGFRA | c.2985C>T p.N995= | Silent (SNP) | VAF 231/490 reads (47%) | catalogued as rs138801854; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC25A45 | c.609G>A p.T203= | Silent (SNP) | VAF 158/343 reads (46%) | catalogued as rs370780233; called by muse, mutect2, varscan2
- TBC1D25 | c.522C>T p.G174= | Silent (SNP) | VAF 117/117 reads (100%) | called by muse, mutect2, varscan2
- TBX4 | c.939C>T p.L313= | Silent (SNP) | VAF 315/597 reads (53%) | catalogued as rs777644345, COSV53606573, COSV53610218; called by muse, mutect2, varscan2
- UCK1 | c.318G>A p.E106= | Silent (SNP) | VAF 19/423 reads (4%) | catalogued as COSV64736204; called by muse, mutect2
- VPS13D | c.10101C>T p.V3367= | Silent (SNP) | VAF 33/517 reads (6%) | called by muse, mutect2
- GH2 | c.457-33C>A | Intron (SNP) | VAF 262/610 reads (43%) | catalogued as COSV60426287, COSV60426704; called by muse, mutect2
- TBC1D29P | n.2788G>A | RNA (SNP) | VAF 196/398 reads (49%) | catalogued as rs761058128, COSV70434072; called by muse, varscan2
